MMRF case MMRF_1579 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/267d0e3b-8dd3-4f8e-8f8e-d75a38d86edb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.0 years (24,840 days); ISS stage: III; Days to last known disease status: 1,295 days (3.5 years); Days to last follow up: 1,295 days (3.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 17 days; Days to treatment end: 731 days (2.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 17 days; Days to treatment end: 60 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 123 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 17: M Protein 5.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 67 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 17.5 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 4.66 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.9 mmol/L; Glucose 6.27 mmol/L.
- Day 100 (ECOG 1): M Protein 0.5 g/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 2.01 g/L; Beta 2 Microglobulin 14.9 µg/mL; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 4.74 ×10⁹/L; Platelets 341 ×10⁹/L; Creatinine 97.2 µmol/L; Calcium 1.73 mmol/L; Albumin 31 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 205 (ECOG 1): M Protein 0.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.47 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 4.12 g/L; Immunoglobulin M 0.73 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.93 ×10⁹/L; Absolute Neutrophil 4.71 ×10⁹/L; Platelets 418 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 7.3 g/dL; Glucose 9.96 mmol/L.
- Day 296 (ECOG 1): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 2.83 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.58 ×10⁹/L; Absolute Neutrophil 2.44 ×10⁹/L; Platelets 287 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 7.37 mmol/L.
- Day 415: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 9.74 g/L; Immunoglobulin A 2.15 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.69 ×10⁹/L; Absolute Neutrophil 2.21 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 6.93 mmol/L.
- Day 472: M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 9.11 g/L; Immunoglobulin A 3.93 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.78 ×10⁹/L; Absolute Neutrophil 2.56 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Albumin 32 g/L; Total Protein 6.9 g/dL; Glucose 5.72 mmol/L.
- Day 590 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 7.56 g/L; Immunoglobulin A 4.3 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.11 ×10⁹/L; Platelets 371 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 5.83 mmol/L.
- Day 653: M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 6.78 g/L; Immunoglobulin A 5.29 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 9.96 mmol/L.
- Day 751: Hemoglobin 7.5 mmol/L; Leukocytes 6.06 ×10⁹/L; Absolute Neutrophil 2.99 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 31 g/L; Total Protein 6.6 g/dL; Glucose 15.3 mmol/L.
- Day 814: Hemoglobin 7.81 mmol/L; Leukocytes 7.13 ×10⁹/L; Absolute Neutrophil 3.88 ×10⁹/L; Platelets 301 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.05 mmol/L; Albumin 33 g/L; Total Protein 7.1 g/dL; Glucose 9.52 mmol/L.
- Day 884: Hemoglobin 8.18 mmol/L; Leukocytes 5.54 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 389 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 5.83 mmol/L.
- Day 1,003 (ECOG 2): M Protein 6.11 g/dL; Immunoglobulin G 65.7 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 5.83 mmol/L; Leukocytes 6.63 ×10⁹/L; Absolute Neutrophil 2.19 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 179 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 3.33 mmol/L; Albumin 27 g/L; Total Protein 12.8 g/dL; Glucose 5.89 mmol/L.
- Day 1,101: M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 7.6 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 9.95 ×10⁹/L; Absolute Neutrophil 8.06 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 7.1 g/dL; Glucose 11.7 mmol/L.
- Day 1,192: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 6.43 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.56 ×10⁹/L; Absolute Neutrophil 2.92 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 6.4 g/dL; Glucose 9.85 mmol/L.
- Day 1,295: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 3.28 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.05 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 6.82 mmol/L.

Other clinical attributes
- Day 17: Weight: 91 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1579_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 17 days.
- Sample MMRF_1579_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 17 days.
